Gene-level copy-number profile of tumor specimen TCGA-VR-A8EZ-01A from TCGA case TCGA-VR-A8EZ, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 47.8 years (17,449 days).
Specimen TCGA-VR-A8EZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.076e8e88-88cb-4ff9-bfaa-890246b7c569.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VR-A8EZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/afeb518c-0d72-4a4a-badb-afb6375a1e41

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 1,332; copy number 2: 18,169; copy number 3: 22,564; copy number 4: 13,315; copy number 5: 3,013; copy number 6: 957; copy number 7: 93; copy number 8: 270; copy number 9: 12; copy number 12: 21; copy number 14: 7; copy number 23: 31; copy number 36: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VR-A8EZ-01A-11D-A36I-01): tumor purity 0.68, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:152,308,283–152,318,364, 2 genes: AC080078.1, AC080078.2.
- chr4:152,337,655–152,338,098, 1 gene: FBXW7-AS1.
- chr9:21,966,929–22,128,103, 8 genes: CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 449 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:214,482,813–214,664,571, 5 genes, copy number 7 (within-gene range 6–7): AL445305.1, KRT18P12, CENPF, ABHD17AP3, UBE2V1P13.
- chr1:241,831,935–243,851,079, 37 genes, copy number 8: AL365366.1, EXO1, RPL23AP20, BECN2, CFL1P4, MAP1LC3C, TUBB8P6, BX571673.1, PLD5, AL591686.2, RN7SKP12, AL591686.1, AL360271.2, RPL10AP5, AL360271.1, AC099785.1, RSL24D1P4, AL445675.1, AL445675.2, AL603825.1, AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P, CEP170, AL606534.1, AL606534.2, SDCCAG8, FCF1P7, MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1.
- chr3:179,097,731–183,555,706, 96 genes, copy number 8–14 (within-gene range 6–14) (broad region; genes not listed).
- chr3:188,941,715–198,222,513, 217 genes, copy number 7–8 (broad region; genes not listed).
- chr7:34,209,465–36,724,549, 48 genes, copy number 8 (within-gene range 5–8): AC009262.1, RNU6-438P, NPSR1-AS1, NPSR1, RPL7P31, NCAPD2P1, RN7SL132P, AC004788.1, DPY19L1, MIR548N, AC005400.1, DPY19L2P1, S100A11P2, TBX20, AC009531.1, AC007652.3, AC007652.2, AC007652.1, AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3, PPP1R14BP4, AC083864.5, AC083864.2, AC083864.4, AC083864.1, AC083864.3, MARK2P13, AC078841.1, EEPD1, AC007327.1, AC007327.2, AC006960.1, AC006960.3, KIAA0895, Y_RNA, ANLN, AC006960.2, AOAH, AOAH-IT1.
- chr11:69,294,151–71,252,577, 46 genes, copy number 23–36 (within-gene range 6–36): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1.

Autosomal genes at a single copy (total copy number 1): 979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
